Surgical pathology report (de-identified scan), TCGA case TCGA-91-6835, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6835-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]
Final Pathologic Diagnosis:

A: Lymph node, 4R subcarinal, resection:
Eight benign lymph nodes.

B: LUNG, Resection:

Specimen: Right Lung; Lower lobe of lung;

Procedure: lobectomy

Specimen laterality: Right

Tumor site: Right lower lobe

Specimen integrity: Intact

Tumor size (greatest dimension): 2.4x 2.4cm

Tumor focality: Unifocal

Tumor histologic type: Adenocarcinoma

Tumor grade: Moderately differentiated

Visceral pleura invasion: Present

Tumor Extension: Not identified

Margins:

Bronchial: Uninvolved by invasive carcinoma

Vascular: Uninvolved by invasive carcinoma

Parenchymal: Uninvolved by invasive carcinoma

Parietal pleural: Not applicable

Chest wall: Not applicable

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: less than 1mm

Specify margin: visceral pleura

Treatment effect: Not applicable

Lymph-vascular invasion: Not identified

Pathologic staging (pTNM):

TNM Descriptors: none

Primary tumor: pT

Regional lymph nodes: pN0

Number examined: 14

Number involved: 0

Distant metastasis: pMX

Additional pathologic findings: Emphysematous changes in uninvolved lung parachyma

C: Lymph nodes, #9 inferior pulmonary, excision:

Two benign lymph nodes.

D: Lymph nodes, lower paratracheal, excision:

Four benign lymph nodes.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Electronically Signed

[REDACTED] ([REDACTED])
[REDACTED]

Signing Location:

Gross Description:

Received are three specimen containers, each labeled with the patient's name,

[page 2 of 2]
" . "

Part A is received in formalin additionally labeled "subcarinal lymph node" and consists of multiple red-brown nodular portions of soft tissue, some of which have a gray-black tinge, grossly consistent with probable anthracotic pigment. Sectioning of the tissue reveals at least eight probable lymph nodes, which range from 0.6 to 1.5 cm in greatest dimension. These lymph node candidates are submitted as follows:

- A1 four whole probable lymph nodes;
- A2 three whole probable lymph nodes;
- A3 remaining soft tissues with possible additional lymph node for microscopic analysis.

This specimen has been submitted in its entirety.

Part B is additionally labeled "right lower lobe" and consists of a lobe of lung with overall dimensions of 15 x 10.2 x 2.2 cm. The pleural surface is purple-tan to pink-gray with focal gray-black pigmentation. The specimen is received with a portion of black ink along one side. There are multiple staple lines present without designation. Additional sectioning reveals a gray-tan to red-brown, firm, well circumscribed, focally degenerative mass with overall dimensions of 2.4 x 2.4 x 2.1 cm. This mass is approximately 3 cm from the bronchial margin of resection. Also this mass corresponds to the overlying inked pleural surface. The remaining lung parenchyma is red-brown to pink-tan and spongy.

Representative sections are submitted as follows:

- B1 vascular and bronchial margin;
- B2 possible lymph node adjacent to bronchial margin;
- B3-6 sections of mass;
- B7,8 uninvolved lung parenchyma.

Part C is received additionally labeled "inferior pulmonary ligament" and consists of a single nodular portion of tan-yellow soft tissue, containing two probable lymph nodes, having greatest dimensions of 0.5 and 0.8 cm. These tissues are submitted entirely in cassette C.

Part D is received additionally labeled "4R lower paratracheal lymph node" and consists of a single nodular portion of red-brown nodular soft tissue, which is 5 mm in greatest dimension. This tissue is submitted in toto in cassette D.

[REDACTED]
[REDACTED]

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Taken: [REDACTED]

END OF REPORT

Source: NCI Genomic Data Commons file 33df5e92-e797-4196-aa6f-1e6dc624eb67 (TCGA-91-6835.BB4510C1-ADDD-42A3-9439-DFC7E43078D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).